Somatic mutation profile of tumor specimen 0DRXEE from CCDI case PBCHFE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Mandible; Age at diagnosis: 7.1 years (2,599 days).
Specimen 0DRXEE: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e192d6ff-66a4-4260-8393-476addbe3c69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRXEU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74625763-01b6-41df-b49b-c0b30392e75c

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACA | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 74/298 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ANK3 | c.10020C>T p.D3340= | Silent (SNP) | VAF 58/301 reads (19%) | catalogued as rs750349884, COSV99779373; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAPT1 | c.846+42C>G | Intron (SNP) | VAF 33/131 reads (25%) | called by muse, mutect2, varscan2
